Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3673, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3673-01A (Primary Tumor).

Diagnosis:

Ileocolic resection material includes a moderately differentiated adenocarcinoma of the colorectal type in the transverse colon, 6.5 cm from the aboral resection margin, with central ulceration and with incipient infiltration of the pericolic fatty tissue (maximum infiltration depth in the perimuscular fatty tissue at the histological section less than 1 mm).

Tumor-free regional lymph nodes. Tumor-free resection margins of small intestine and colon. Tumor-free mesenteric resection margin. Tumor-free appendix. Tumor-free fatty tissue of the omentum. Also so-called retention polyp of the colon mucosa.

Tumor stage: pT3 pN0 (0/41) pMX; G2, L0 V0 R0

Source: NCI Genomic Data Commons file dab07318-c51a-4758-aa37-a637d9aee1d9 (TCGA-AA-3673.36B13EAC-D940-40DC-B7E3-C215165D303B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).